Surgical pathology report (de-identified scan), TCGA case TCGA-BW-A5NQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site St. Joseph's Medical Center-(MD), specimen TCGA-BW-A5NQ-01A (Primary Tumor).

[page 1 of 2]
Specimen Inquiry

PAGE 1

PATIENT: [REDACTED]

ACCT #: [REDACTED]

LOC: [REDACTED]

GE/SX: [REDACTED]

Flags: *H *L = Critical H,L = Abnormal #=Delta ** = Alpha Abn * Mic Abn

ORDERED: 88304, 88307, 88313, LEVEL III - GRO, LEVEL V - GROSS, SPECIAL STAINS

SURGICAL PROCEDURES:

GALLBLADDER, RESECTION

CLINICAL HISTORY

OTHER SPECIAL CONSULTATION: TCGA PROJECT

GROSS DESCRIPTION

A. The specimen is submitted fresh as "liver segment V and VI" and consists of a section of liver weighing 421 grams and measuring 14 x 11 x 8 cm. The external surface is red brown having a slight nodular appearance. The surgical margin will be marked with black dye. Sectioning reveals the normal nutmeg color interrupted by a friable tan lobulated mass measuring 7 x 4.5 x 4.5 cm. The mass appears to be well circumscribed and encapsulated and approaches to within 1.5 cm of the surgical margin and 0.5 cm to the external surface. Representative sections are submitted, 10 (7).

B. The specimen is submitted in formalin as "gallbladder" and consists of a gallbladder measuring 7 x 3 x 1.3 cm. The external surface is pale yellow to purple tan. Upon opening the gallbladder contains a scant of dark green bile. Calculi are not grossly identified. The gallbladder wall measures 0.2 cm in thickness. The mucosa is dark green and trabeculated. The resected margin of the cystic duct does not grossly appear to be dilated and not occluded. Representative sections are submitted, 3 (1).

FINAL DIAGNOSIS

A. LIVER, SEGMENT V AND VI, RESECTION:

- POORLY DIFFERENTIATED HEPATOCELLULAR CARCINOMA (7 CM).
- RESECTION MARGIN CLEAR.
- BACKGROUND LIVER SHOWS CIRRHOSIS.

B. GALLBLADDER, CHOLECYSTECTOMY:

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver, hepatic NOS
C22.0
JW 2/4/13

Patient: [REDACTED]

[page 2 of 2]
Specimen Inquiry

Patient: [REDACTED]

(Continued)

FINAL DIAGNOSIS

(Continued)

- CHRONIC CHOLECYSTITIS.

SYNOPTIC REPORT

SYNOPTIC REPORT: LIVER (AND INTRAHEPATIC BILE DUCTS)
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: PARTIAL HEPATECTOMY (SEGMENT V-VI HEPATIC RESECTION)

TUMOR FOCALITY: UNIFOCAI

TUMOR SIZE: 7 CM

HISTOLOGIC TYPE: HEPATOCELLULAR CARCINOMA

HISTOLOGIC GRADE: POORLY DIFFERENTIATED (GRADE 3 OF 4)

TUMOR EXTENSION: TUMOR CONFINED TO LIVER

VASCULAR INVASION: NOT IDENTIFIED

f,,, INVASION OF MAJOR BRANCH OF PORTAL/HEPATIC VEIN: NOT IDENTIFIED
INVASION OF ADJACENT ORGANS/STRUCTURES: ABSENT

MARGINS:

f,,, PARENCHYMAL: UNINVOLVED

f,,f,,, DISTANCE TO CLOSEST MARGIN: 1.2 CM FROM THE RESECTION MARGIN

LYMPH NODES:

f,,, # INVOLVED/ # EXAMINED: N/A

OTHER PERTINENT FINDINGS:

- THE UNINVOLVED LIVER SHOWS STEATOSIS AND CIRRHOSIS (ISHAK STAGE - 6 OF 6), CONFIRMED ON A TRICHROME STAIN.

pTNM STAGE: pT1

Signed (Electronically) < SIGNATURE ON FILE >

PATHOLOGIST

Patient: [REDACTED]

Source: NCI Genomic Data Commons file 69a805f6-39e2-4ea8-b5a9-f269d39586b6 (TCGA-BW-A5NQ.D56121DE-22A7-44D8-97EF-E33D395ABAF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).